Gene-level copy-number profile of tumor specimen ALCH-B2YD-TTP1-A from ALCHEMIST case ALCH-B2YD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.1 years (27,442 days).
Specimen ALCH-B2YD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d8ea2053-3d86-4ddd-9935-8e0b180d7875.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2YD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/82b9cec0-2548-4af1-b71f-d0cf0f1900d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,238; copy number 2: 55,193; copy number 3: 458; copy number 4: 22; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:98,617,285–98,629,869, 1 gene: NPTX2.
- chr10:128,958,772–128,960,062, 1 gene: AL355537.1.
- chr12:128,826,836–128,827,579, 1 gene: AC108704.1.
- chr14:95,711,747–95,757,656, 1 gene (within-gene range 0–2): AL139020.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:2,851,230–2,881,407, 1 gene, copy number 6 (within-gene range 4–6): SERPINB9P1.

Autosomal genes at a single copy (total copy number 1): 382. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
